Somatic mutation profile of tumor specimen C3L-01156-01 (aliquot CPT0218960006) from CPTAC case C3L-01156, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.5 years (20,999 days).
Specimen C3L-01156-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3f255f3-e98b-4917-b353-36b43f8a6f25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01156-31 (Blood Derived Normal), aliquot CPT0220410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d1c526e-6f56-4271-9c83-387f04560b75

The open-access MAF lists 84 somatic variants for this specimen: 52 protein-altering or splice-affecting, 22 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 22, Intron 3, Splice Region 2, Nonsense Mutation 2, RNA 2, Splice Site 2, 3'Flank 2, 5'UTR 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 3469/8156 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RPL5 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 56/151 reads (37%) | catalogued as rs121434405, CM086903; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEACAM3 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 110/427 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs1367815305; called by muse, mutect2, varscan2
- CFAP206 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as rs377549577, COSV51535435; called by muse, mutect2, varscan2
- COLEC11 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 126/399 reads (32%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.84); catalogued as rs754115098, COSV52598860; called by muse, mutect2, varscan2
- CYP2C19 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368758960; called by muse, mutect2, varscan2
- GRM1 | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 196/574 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768250872, COSV51110462, COSV51132186; called by muse, mutect2, varscan2
- HECW2 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.579); catalogued as rs145526330; called by muse, mutect2, varscan2
- HPD | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 206/482 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780501941, CM160167; ClinVar: uncertain significance; called by mutect2, varscan2
- KCNH5 | c.676T>C p.F226L | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.574); catalogued as rs772687794; called by muse, mutect2, varscan2
- KLK3 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs978892095, COSV58099501; called by muse, mutect2, varscan2
- KMO | c.957G>A p.A319= | Splice Region (SNP) | VAF 45/110 reads (41%) | catalogued as rs762411440, COSV100844662, COSV63806037; called by muse, mutect2, varscan2
- LILRB1 | c.1600C>T p.R534* (on ENST00000427581; = p.R484* on NM_006669.6) | Nonsense Mutation (SNP) | VAF 97/326 reads (30%) | catalogued as rs376266152; called by muse, varscan2
- MAN2B1 | c.64T>C p.W22R | Missense Mutation (SNP) | VAF 120/676 reads (18%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1329492928; called by muse, mutect2, varscan2
- MOS | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1353569477; called by muse, mutect2, varscan2
- NCF1 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 164/799 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as rs147659773; called by muse, mutect2, varscan2
- NPC1L1 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.078); catalogued as rs371689322, COSV56923229; called by muse, mutect2, varscan2
- OR11H4 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV59560456; called by muse, mutect2, varscan2
- PTEN | c.373A>G p.K125E | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64292010, COSV64310749; called by muse, mutect2, varscan2
- RIMS2 | c.3134G>A p.R1045Q (on ENST00000666250 / NM_001348490.2; = p.R853Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/271 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.932); catalogued as rs776394480, COSV51665828; called by muse, mutect2, varscan2
- SHANK2 | c.3527C>T p.T1176M | Missense Mutation (SNP) | VAF 140/419 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs782614044; called by muse, mutect2, varscan2
- SLC5A9 | c.339C>T p.N113= | Splice Region (SNP) | VAF 87/201 reads (43%) | catalogued as rs761673642, COSV52584636, COSV52585173; called by muse, mutect2, varscan2
- SPNS1 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 93/257 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs370326654; called by muse, mutect2, varscan2
- STUB1 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99555897; called by muse, mutect2, varscan2
- TACC2 | c.5573+1G>A p.X1858_splice | Splice Site (SNP) | VAF 122/239 reads (51%) | catalogued as rs1188697625; called by muse, mutect2, varscan2
- UNC93B1 | c.923G>C p.G308A | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as rs1442000007; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABR | c.1754A>G p.E585G (on ENST00000302538 / NM_021962.5; = p.E548G on NM_001092.5) | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ACAP3 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 152/350 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- CD36 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP52 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTNNA2 | c.1202T>C p.V401A | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- EMB | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- FAM20C | c.1673G>T p.R558L | Missense Mutation (SNP) | VAF 84/335 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- FBXO34 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- FMN1 | c.3799A>T p.I1267L (on ENST00000616417 / NM_001277313.2; = p.I1044L on NM_001103184.4) | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- GSKIP | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- HMCN2 | c.13822del p.E4608Rfs*80 | Frame Shift Del (DEL) | VAF 110/408 reads (27%) | called by mutect2, pindel, varscan2
- HOXD1 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 146/398 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- MAPK3 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 121/351 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OAF | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 142/392 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.164); called by muse, varscan2
- PCDH11Y | c.632T>C p.I211T (on ENST00000400457 / NM_032973.2; = p.I200T on NM_032971.3) | Missense Mutation (SNP) | VAF 98/133 reads (74%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- PLCD3 | c.2222C>T p.A741V | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- PPP2CA | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN20 | c.879A>C p.Q293H | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); called by mutect2, varscan2
- RHOB | c.485A>G p.K162R | Missense Mutation (SNP) | VAF 128/389 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- RHPN2 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 127/501 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RIMBP2 | c.2933T>A p.L978H | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A3 | c.158-1G>C p.X53_splice | Splice Site (SNP) | VAF 31/110 reads (28%) | called by muse, mutect2, varscan2
- SPAG7 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TENM1 | c.7736G>A p.G2579E | Missense Mutation (SNP) | VAF 58/72 reads (81%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- TRAPPC6A | c.267C>A p.H89Q (on ENST00000585934 / NM_001270891.2; = p.H103Q on NM_024108.3) | Missense Mutation (SNP) | VAF 34/377 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.254); called by muse, mutect2
- TRIM56 | c.1387T>C p.F463L | Missense Mutation (SNP) | VAF 90/322 reads (28%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ADAMTSL1 | c.4542G>A p.R1514= | Silent (SNP) | VAF 89/117 reads (76%) | called by muse, mutect2, varscan2
- AKAP13 | c.714G>A p.P238= | Silent (SNP) | VAF 81/228 reads (36%) | catalogued as rs374214307; called by muse, mutect2, varscan2
- ANKRD34C | c.1333C>A p.R445= | Silent (SNP) | VAF 91/229 reads (40%) | catalogued as COSV69855403; called by muse, mutect2, varscan2
- DAB2 | c.135C>T p.G45= | Silent (SNP) | VAF 61/210 reads (29%) | catalogued as rs758227666, COSV57914254; called by muse, mutect2, varscan2
- DDC | c.807C>T p.H269= | Silent (SNP) | VAF 176/680 reads (26%) | catalogued as rs138333052; called by muse, mutect2, varscan2
- FBN2 | c.7878C>T p.H2626= | Silent (SNP) | VAF 117/328 reads (36%) | catalogued as rs587780943; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- FSIP2 | c.5973G>A p.L1991= | Silent (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2, varscan2
- FSTL4 | c.972C>T p.S324= | Silent (SNP) | VAF 131/412 reads (32%) | catalogued as rs190908572; called by muse, varscan2
- GARRE1 | c.1593C>T p.G531= | Silent (SNP) | VAF 69/340 reads (20%) | called by muse, mutect2, varscan2
- IGKV2D-30 | c.264C>T p.S88= | Silent (SNP) | VAF 190/565 reads (34%) | catalogued as rs202163595; called by muse, mutect2, varscan2
- NKD2 | c.363C>T p.D121= | Silent (SNP) | VAF 83/235 reads (35%) | catalogued as rs149056716, COSV99723897; called by muse, mutect2, varscan2
- NLRP8 | c.1692C>T p.N564= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as rs200709261, COSV99404703; called by muse, mutect2, varscan2
- NUP62 | c.1527G>A p.R509= | Silent (SNP) | VAF 90/334 reads (27%) | catalogued as rs371693868; called by muse, mutect2, varscan2
- OGDHL | c.2205G>A p.G735= | Silent (SNP) | VAF 98/170 reads (58%) | catalogued as rs189326161; called by muse, mutect2, varscan2
- PLCB2 | c.975G>A p.S325= | Silent (SNP) | VAF 112/286 reads (39%) | catalogued as rs373509189; called by muse, mutect2, varscan2
- RNF44 | c.1170G>A p.R390= | Silent (SNP) | VAF 44/144 reads (31%) | called by muse, mutect2, varscan2
- SELENOI | c.147G>A p.A49= | Silent (SNP) | VAF 46/136 reads (34%) | catalogued as rs372437710, COSV99564304; called by muse, mutect2, varscan2
- SLC9A3 | c.636C>T p.I212= | Silent (SNP) | VAF 66/223 reads (30%) | catalogued as rs762488428, COSV53799822; called by muse, mutect2, varscan2
- SLCO4A1 | c.138C>T p.S46= | Silent (SNP) | VAF 41/255 reads (16%) | catalogued as rs968540636, COSV53891438; called by muse, mutect2, varscan2
- SSX3 | c.129G>A p.S43= | Silent (SNP) | VAF 46/65 reads (71%) | catalogued as rs782595527, COSV53644776; called by muse, mutect2, varscan2
- TMC4 | c.438G>A p.A146= (on ENST00000617472 / NM_001145303.3; = p.A140= on NM_144686.4) | Silent (SNP) | VAF 43/259 reads (17%) | catalogued as rs542277008, COSV99824860; called by muse, mutect2, varscan2
- TSPAN32 | c.453C>T p.D151= | Silent (SNP) | VAF 90/170 reads (53%) | catalogued as rs541981635, COSV51718464; called by muse, mutect2, varscan2
- ADCY10P1 | n.3646A>C | RNA (SNP) | VAF 23/99 reads (23%) | called by mutect2, varscan2
- ALKBH5 | c.-293C>T | 5'UTR (SNP) | VAF 14/304 reads (5%) | catalogued as rs1031805429; called by muse, mutect2
- ATP10A | c.449+374C>A | Intron (SNP) | VAF 67/184 reads (36%) | called by muse, mutect2, varscan2
- ERCC2 | c.*23C>T | 3'UTR (SNP) | VAF 86/334 reads (26%) | catalogued as rs556864330; called by muse, mutect2, varscan2
- ERGIC3 | chr20:35559394 G>A | 3'Flank (SNP) | VAF 94/267 reads (35%) | catalogued as rs560343901; called by muse, mutect2, varscan2
- LDHA | chr11:18407980 A>G | 3'Flank (SNP) | VAF 80/211 reads (38%) | called by muse, mutect2, varscan2
- MSLNL | c.504-40C>T | Intron (SNP) | VAF 114/326 reads (35%) | catalogued as rs778729896; called by muse, mutect2, varscan2
- OR10D1P | n.385C>T | RNA (SNP) | VAF 79/324 reads (24%) | catalogued as rs1448562523; called by muse, mutect2, varscan2
- SPACA7 | c.94+2236G>A | Intron (SNP) | VAF 104/294 reads (35%) | catalogued as rs950775018; called by muse, mutect2, varscan2
- ZNF543 | c.-6C>G | 5'UTR (SNP) | VAF 79/358 reads (22%) | called by muse, mutect2, varscan2
